MMRF case MMRF_1032 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/12e4b465-9473-432f-a8e3-d5363cbb3960

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Dead; Days to death: 934 days (2.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.0 years (28,110 days); ISS stage: II; Days to last known disease status: 934 days (2.6 years); Days to last follow up: 934 days (2.6 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 39 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 52 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 439 days (1.2 years); Days to treatment end: 725 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 439 days (1.2 years); Days to treatment end: 578 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 612 days (1.7 years); Days to treatment end: 934 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 726 days (2.0 years); Days to treatment end: 934 days (2.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 934.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 2): M Protein 3.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 39.2 mg/dL; Immunoglobulin G 47.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 8.9 g/dL; Glucose 5.89 mmol/L.
- Day 70 (ECOG 3): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.772 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.344 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 268 ×10⁹/L.
- Day 173 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.94 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 226 ×10⁹/L.
- Day 236 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 369 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.76 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 206 ×10⁹/L.
- Day 439 (ECOG 1): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.65 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 1.37 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 551 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Immunoglobulin G 8.29 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 640 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.37 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.01 mmol/L.
- Day 726 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 817 (ECOG 1): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.19 mg/dL; Immunoglobulin G 8.78 g/L; Immunoglobulin A 2.7 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 908 (ECOG 1): M Protein 0.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -2: Weight: 101 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1032_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1032_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
